Somatic mutation profile of tumor specimen TCGA-DU-6407-02A (aliquot TCGA-DU-6407-02A-12D-A36O-08) from TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.6 years (13,021 days).
Specimen TCGA-DU-6407-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db83be03-a08b-4ed2-9423-fff2d461d030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6407-10A (Blood Derived Normal), aliquot TCGA-DU-6407-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd74c073-8ae2-4c50-a2dd-4304dbc768b5

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Frame Shift Del 5, In Frame Del 3, Frame Shift Ins 1, RNA 1, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 53/68 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057523496, COSV52819746, COSV53616876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs369536848, COSV58643276; called by muse, mutect2, varscan2
- BAD | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1239444599; called by muse, mutect2, varscan2
- CEP164 | c.3991T>C p.S1331P | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV54040521; called by muse, mutect2, varscan2
- CYP26B1 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228321015, COSV50011655; called by muse, mutect2, varscan2
- DNAH2 | c.11419_11421del p.F3807del | In Frame Del (DEL) | VAF 34/66 reads (52%) | catalogued as rs1478497162; called by mutect2, pindel, varscan2
- ELK3 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs202181482, COSV57385666, COSV57387764; called by muse, mutect2, varscan2
- IGF2R | c.5768C>T p.A1923V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs368781979; called by muse, mutect2, varscan2
- MICAL2 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs746333925; called by muse, mutect2, varscan2
- MIPEP | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV66300433; called by muse, mutect2, varscan2
- PLA2R1 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); catalogued as rs960101159, COSV51775202; called by muse, mutect2
- PTPRZ1 | c.98_100del p.V33del | In Frame Del (DEL) | VAF 53/234 reads (23%) | catalogued as rs748245145; called by pindel, varscan2
- SCN1A | c.3502G>A p.V1168I (on ENST00000303395 / NM_001202435.3; = p.V1157I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.245); catalogued as rs146374754; ClinVar: uncertain significance; called by muse, mutect2
- SDSL | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs149197891; called by muse, mutect2, varscan2
- SLC20A1 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1009014063; called by muse, mutect2, varscan2
- ZNF324B | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs760101692, COSV60741881; called by muse, mutect2
- ZNF813 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV67175859; called by muse, mutect2, varscan2
- ANK1 | c.36del p.D13Tfs*38 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- ARSG | c.454+2T>A p.X152_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ATP6V0C | c.451_458del p.I151Hfs*16 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- ATRX | c.5636T>G p.L1879* | Nonsense Mutation (SNP) | VAF 131/321 reads (41%) | called by muse, mutect2, varscan2
- BCL6B | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL5A3 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CUL4B | c.1165_1181del p.F389Pfs*6 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- DMWD | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERICH3 | c.3940T>G p.S1314A | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 25/441 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.672); called by muse, mutect2
- FOXRED1 | c.138_141del p.R48Pfs*19 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- FRAS1 | c.7191C>A p.D2397E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- GPR50 | c.1483G>C p.A495P | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GRIN2C | c.1203del p.H402Tfs*2 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- LCK | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- LGSN | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- MAGEC1 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MTHFSD | c.351G>T p.Q117H (on ENST00000360900 / NM_001159377.2; = p.Q116H on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST1 | c.1685C>G p.P562R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NLRP1 | c.949_957del p.L317_G319del | In Frame Del (DEL) | VAF 33/205 reads (16%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2
- PSMB7 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIF1 | c.4373T>G p.I1458R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RTP5 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- THAP6 | c.477_478insAG p.G160Rfs*4 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ZNF274 | c.559C>G p.H187D (on ENST00000610905; = p.H82D on NM_016324.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2
- ANKRD10 | c.1047C>T p.H349= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- C1orf116 | c.1203A>G p.A401= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- FAT1 | c.315A>T p.T105= | Silent (SNP) | VAF 38/53 reads (72%) | called by muse, varscan2
- GATA3 | c.411G>A p.S137= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs745734873, COSV60518006; called by muse, mutect2, varscan2
- GPR108 | c.789C>G p.L263= (on ENST00000264080 / NM_001080452.1; = p.L21= on NM_020171.2) | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- HELZ | c.4044T>C p.A1348= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV62378124; called by muse, mutect2, varscan2
- PCDHB6 | c.2151G>A p.A717= | Silent (SNP) | VAF 55/247 reads (22%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4878T>C p.R1626= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100737932; called by muse, mutect2, varscan2
- PPP3R2 | c.195C>T p.D65= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs894352330, COSV100701600; called by muse, mutect2, varscan2
- RETREG1 | c.1170G>A p.T390= (on ENST00000306320 / NM_001034850.2; = p.T249= on NM_019000.4) | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs369353830; called by muse, mutect2, varscan2
- SCAPER | c.3273A>G p.Q1091= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2
- ZNF266 | c.969C>G p.P323= | Silent (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- HOMER3 | c.*153C>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as rs1020417998, COSV99651027; called by muse, mutect2, varscan2
- MIR30B | n.54G>T | RNA (SNP) | VAF 28/106 reads (26%) | catalogued as rs752360840; called by muse, varscan2
